HCMI case HCM-BROD-0415-C71 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a42da11c-f1c5-4641-98f4-535c675d43d5

Demographics
Sex at birth: female; Race: white; Year of birth: 1959; Vital status: Dead; Days to death: 442 days (1.2 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 53.3 years (19,455 days); WHO CNS grade: Grade IV; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No.
   Pathology details: Necrosis present: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -7 days.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Adjuvant; Initial disease status: Residual Disease.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (3 entries)
- Days to follow up: 328 days; Karnofsky performance status: 80.
- Days to follow up: 432 days (1.2 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 0.

Molecular and laboratory tests
- IDH1 (IHC): Negative; Amino-acid change: R132H.
- MGMT methylation: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 99 kg; Height: 166 cm; BMI: 35.9.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0415-C71-02B: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-0415-C71-02B-01-S2-HE: Section location: Bottom; Percent tumor cells: 72; Percent tumor nuclei: 89; Percent normal cells: 9; Percent necrosis: 5; Percent stromal cells: 14; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-BROD-0415-C71-02B-01-S1-HE: Section location: Top; Percent tumor cells: 78; Percent tumor nuclei: 88; Percent normal cells: 11; Percent necrosis: 0; Percent stromal cells: 11; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-BROD-0415-C71-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0415-C71-85R: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 9.
